Gene-level copy-number profile of tumor specimen TCGA-63-6202-01A from TCGA case TCGA-63-6202, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-63-6202-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.060187c7-b2d2-4d89-b565-ea495ef7f2e7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-6202-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02bed4f7-faac-4e21-b83d-100a41b75099

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 6,210; copy number 3: 18,265; copy number 4: 19,024; copy number 5: 7,195; copy number 6: 2,220; copy number 7: 3,414; copy number 8: 754; copy number 9: 1,876; copy number 11: 563; copy number 12: 165; copy number 13: 58; copy number 14: 30; copy number 17: 31; copy number 19: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-6202-01A-11D-1816-01): tumor purity 0.42, ploidy 2.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,729 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,017,468–162,979,793, 776 genes, copy number 9–19 (within-gene range 8–19) (broad region; genes not listed).
- chr2:79,135,503–80,870,190, 16 genes, copy number 9: REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1.
- chr4:28,711,198–32,228,543, 24 genes, copy number 9–11: RN7SL101P, MIR4275, MESTP3, LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1.
- chr4:35,487,812–36,641,939, 10 genes, copy number 9: SEC63P2, RNU6-573P, ARAP2, AC098827.1, AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1.
- chr5:58,198–45,895,970, 710 genes, copy number 11–13 (broad region; genes not listed).
- chr7:28,953,358–29,514,667, 12 genes, copy number 9 (within-gene range 7–9): TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4.
- chr8:41,929,479–74,548,617, 499 genes, copy number 9 (broad region; genes not listed).
- chr8:74,603,244–74,633,320, 2 genes, copy number 9: PCBP2P2, AC115837.1.
- chr8:106,265,435–145,066,685, 577 genes, copy number 9 (broad region; genes not listed).
- chr14:32,329,298–32,837,684, 1 gene, copy number 12 (within-gene range 3–12): AKAP6.
- chr14:32,879,246–33,804,176, 4 genes, copy number 12: AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr14:34,432,788–37,172,606, 77 genes, copy number 12–17 (within-gene range 3–17) (broad region; genes not listed).
- chr14:39,432,599–43,314,803, 21 genes, copy number 9–13 (within-gene range 3–13): AL049828.1, AL049828.2, AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
